Somatic mutation profile of tumor specimen MP2PRT-PAUMVX-TMP1-A (aliquot MP2PRT-PAUMVX-TMP1-A-1-0-D-A80K-36) from MP2PRT case MP2PRT-PAUMVX, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.8 years (2,856 days).
Specimen MP2PRT-PAUMVX-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e3c1af48-6cca-476a-8729-e3f82e2782a9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUMVX-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUMVX-NB1-A-1-0-D-A80K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c97b3f96-3006-4117-a48b-8889d2b93218

The open-access MAF lists 30 somatic variants for this specimen: 18 protein-altering or splice-affecting, 9 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 9, In Frame Del 2, 5'UTR 1, Intron 1, Frame Shift Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.5039_5041del p.S1680del | In Frame Del (DEL) | VAF 126/446 reads (28%) | hotspot (GDC flag); catalogued as rs587783502; called by pindel, varscan2
- FLT3 | c.2508_2510del p.I836del | In Frame Del (DEL) | VAF 127/224 reads (57%) | catalogued as rs121913490; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- BCAM | c.1162G>A p.G388S | Missense Mutation (SNP) | VAF 144/321 reads (45%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.606); catalogued as rs759819008; called by muse, mutect2, varscan2
- HMCN1 | c.4112C>T p.S1371L | Missense Mutation (SNP) | VAF 65/209 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs977139633; called by muse, mutect2, varscan2
- MINAR1 | c.2636G>A p.R879H | Missense Mutation (SNP) | VAF 23/222 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.757); catalogued as rs757430018; called by muse, mutect2, varscan2
- PCNX1 | c.6884A>G p.H2295R | Missense Mutation (SNP) | VAF 19/280 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as rs540546846; called by muse, mutect2
- PLEKHG4B | c.1243C>T p.R415W (on ENST00000283426; = p.R771W on NM_052909.5) | Missense Mutation (SNP) | VAF 95/333 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.139); catalogued as rs193920840, COSV52056902; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLEKHG7 | c.143C>T p.S48L | Missense Mutation (SNP) | VAF 60/525 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as rs768522315; called by muse, mutect2, varscan2
- STOX2 | c.2636G>A p.R879H | Missense Mutation (SNP) | VAF 58/533 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as rs1344767661; called by muse, mutect2, varscan2
- ADGRL3 | c.317G>A p.S106N (on ENST00000506720 / NM_001322402.2; = p.S38N on NM_015236.6) | Missense Mutation (SNP) | VAF 98/406 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- ANKK1 | c.1259A>G p.D420G | Missense Mutation (SNP) | VAF 50/526 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.696); called by muse, mutect2
- CLSPN | c.2720A>G p.N907S | Missense Mutation (SNP) | VAF 138/252 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- HEXD | c.1352_1353del p.V451Afs*92 (on ENST00000327949 / NM_001369487.1; = p.C481Hfs*36 on NM_173620.3) | Frame Shift Del (DEL) | VAF 113/798 reads (14%) | called by mutect2, pindel, varscan2
- KCNH2 | c.2694C>A p.D898E | Missense Mutation (SNP) | VAF 91/204 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MAPK4 | c.1751A>T p.K584I | Missense Mutation (SNP) | VAF 22/361 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- NEK10 | c.502G>A p.V168I | Missense Mutation (SNP) | VAF 81/184 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- OR52N5 | c.209T>C p.F70S | Missense Mutation (SNP) | VAF 132/424 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by mutect2, varscan2
- PARD3B | c.2714T>G p.L905R (on ENST00000406610 / NM_001302769.2; = p.L836R on NM_057177.7) | Missense Mutation (SNP) | VAF 34/560 reads (6%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.548); called by muse, mutect2
- HLCS | c.627G>A p.P209= | Silent (SNP) | VAF 105/481 reads (22%) | catalogued as rs73196003, COSV60797702; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IGDCC3 | c.1269C>A p.L423= | Silent (SNP) | VAF 118/250 reads (47%) | called by muse, mutect2, varscan2
- LRRC75A | c.792G>A p.T264= | Silent (SNP) | VAF 46/470 reads (10%) | catalogued as rs780204244, COSV63359226; called by muse, mutect2
- ODF3B | c.630C>T p.L210= | Silent (SNP) | VAF 58/703 reads (8%) | catalogued as rs778348925; called by muse, mutect2
- PHYHIPL | c.903T>G p.P301= | Silent (SNP) | VAF 23/402 reads (6%) | called by muse, mutect2
- PPFIA2 | c.3423G>A p.L1141= | Silent (SNP) | VAF 55/381 reads (14%) | called by muse, mutect2, varscan2
- RERE | c.2793G>A p.P931= | Silent (SNP) | VAF 243/513 reads (47%) | catalogued as rs764179485, COSV61942582; called by muse, mutect2, varscan2
- RRP1 | c.807C>T p.P269= | Silent (SNP) | VAF 37/411 reads (9%) | catalogued as rs774930391, COSV101513845, COSV101513866; called by muse, mutect2
- UNC5C | c.2202T>C p.F734= | Silent (SNP) | VAF 142/518 reads (27%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73846059 G>A | 5'Flank (SNP) | VAF 117/255 reads (46%) | catalogued as rs759504135; called by muse, mutect2, varscan2
- CCDC150 | c.1866+756C>T | Intron (SNP) | VAF 122/381 reads (32%) | catalogued as rs1038991466, COSV55875908; called by muse, mutect2, varscan2
- FHL2 | c.-86G>A | 5'UTR (SNP) | VAF 48/898 reads (5%) | called by muse, mutect2
